Somatic mutation profile of tumor specimen C3N-03235-03 (aliquot CPT0181090006) from CPTAC case C3N-03235, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 53.9 years (19,697 days).
Specimen C3N-03235-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e41b1228-58fd-40e2-87b8-6cde3f8f74fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03235-71 (Blood Derived Normal), aliquot CPT0181190002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f61e3ef-8f2b-4b9e-8c85-3c281f9d143f

The open-access MAF lists 161 somatic variants for this specimen: 119 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 37, Nonsense Mutation 10, 5'UTR 3, Frame Shift Ins 1, In Frame Del 1, Splice Region 1, 5'Flank 1, Intron 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR7A3 | c.542C>G p.T181R | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.048); catalogued as COSV64389738; called by muse, mutect2
- AMER1 | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 57/598 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV57655105; called by muse, mutect2
- ANKLE2 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 32/357 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1372791466; called by muse, mutect2
- ANKRD30B | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 24/473 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.266); catalogued as rs1345293766; called by muse, mutect2
- APC2 | c.5143G>C p.D1715H | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs763408567; called by muse, mutect2
- ASZ1 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52911595; called by muse, mutect2
- ATP1B4 | c.963G>C p.K321N (on ENST00000218008 / NM_001142447.3; = p.K317N on NM_012069.5) | Missense Mutation (SNP) | VAF 45/536 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.134); catalogued as COSV54314715; called by muse, mutect2
- B3GLCT | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 26/387 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as rs780907884; called by muse, mutect2
- BRD7 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as rs946193289; called by muse, mutect2
- C1R | c.965A>C p.K322T (on ENST00000536053 / NM_001354346.2; = p.K308T on NM_001733.7) | Missense Mutation (SNP) | VAF 26/301 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs775903518; called by muse, mutect2
- CEP290 | c.5284C>T p.R1762C | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs373307908; ClinVar: uncertain significance; called by muse, mutect2
- CFAP47 | c.264G>C p.L88F | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV52890877; called by muse, mutect2, varscan2
- CLDN16 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs762831659, COSV53227188; called by muse, mutect2, varscan2
- CUL1 | c.330G>C p.L110F | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.109); catalogued as COSV57390182; called by muse, mutect2
- DLGAP4 | c.2134C>T p.R712W (on ENST00000339266 / NM_001365621.1; = p.R709W on NM_014902.6) | Missense Mutation (SNP) | VAF 19/360 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1487528852, COSV100211630; called by muse, mutect2
- DNAH10 | c.7841G>A p.R2614H (on ENST00000409039; = p.R2553H on NM_207437.3) | Missense Mutation (SNP) | VAF 42/557 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776555856, COSV68998743; called by muse, mutect2
- EIF3K | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 29/309 reads (9%) | catalogued as rs772079164; called by muse, mutect2
- ELN | c.1453_1488del p.V485_G496del | In Frame Del (DEL) | VAF 66/638 reads (10%) | catalogued as rs782202364; called by muse*, mutect2
- FBRSL1 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 54/498 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as rs919660494; called by muse, mutect2
- FRAS1 | c.11951C>T p.A3984V | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as rs374171667; called by muse, mutect2
- FRMPD4 | c.3935A>G p.H1312R | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); catalogued as COSV101042955; called by muse, mutect2
- GLI2 | c.1772C>T p.P591L (on ENST00000361492 / NM_001374353.1; = p.P608L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/565 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs149800897; called by muse, mutect2
- HECTD4 | c.11905G>A p.A3969T | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1490517649, COSV66386570; called by muse, mutect2, varscan2
- KANK2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 42/488 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs770266562; called by muse, mutect2
- KMT2A | c.774G>T p.R258S | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs781870146; called by muse, mutect2
- KRT85 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs773634498, COSV57737355; called by muse, mutect2
- MAGEL2 | c.1595C>T p.P532L | Missense Mutation (SNP) | VAF 44/515 reads (9%) | SIFT tolerated, low confidence (1); catalogued as rs1374185036; called by muse, mutect2
- MECOM | c.10G>A p.E4K (on ENST00000468789 / NM_001105078.4; = p.E192K on NM_004991.4) | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs771927221, COSV52963029; called by muse, mutect2, varscan2
- MRS2 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs150621144; called by muse, mutect2, varscan2
- NEFM | c.2485G>A p.V829I | Missense Mutation (SNP) | VAF 33/456 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as rs371207848; called by muse, mutect2
- NXF1 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 20/342 reads (6%) | catalogued as COSV53674655; called by muse, mutect2
- OR4A16 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 36/473 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs1451862236, COSV100125039, COSV59042425; called by muse, mutect2
- PADI4 | c.1631G>C p.R544T | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV64924762; called by muse, mutect2, varscan2
- POM121L12 | c.113G>A p.S38N | Missense Mutation (SNP) | VAF 24/449 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs1385545410; called by muse, mutect2
- PPP1R3C | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 23/271 reads (8%) | catalogued as rs369970199; called by muse, mutect2
- SCN9A | c.2147G>T p.R716I (on ENST00000303354; = p.R705I on NM_002977.3) | Missense Mutation (SNP) | VAF 28/411 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV57609267; called by muse, mutect2
- SLC52A2 | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 24/620 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs371806077; ClinVar: uncertain significance; called by muse, mutect2
- SMARCA4 | c.4841G>A p.R1614Q | Missense Mutation (SNP) | VAF 24/509 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.194); catalogued as rs878854233; ClinVar: uncertain significance; called by muse, mutect2
- SPDYE3 | c.1021G>C p.G341R | Missense Mutation (SNP) | VAF 38/492 reads (8%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.987); catalogued as COSV60107905; called by muse, mutect2
- STK26 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV61230233; called by muse, mutect2
- SULF2 | c.2411A>G p.N804S | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs772379006; called by muse, mutect2, varscan2
- TIMELESS | c.2248C>T p.L750F | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as rs767552466; called by muse, mutect2
- TMC8 | c.749G>A p.W250* | Nonsense Mutation (SNP) | VAF 38/402 reads (9%) | catalogued as rs747099801; called by muse, mutect2
- TTN | c.31648C>G p.P10550A (on ENST00000591111; = p.P9623A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/269 reads (12%) | PolyPhen benign (0); catalogued as COSV59932487; called by muse, mutect2, varscan2
- TUBA3E | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.599); catalogued as rs766077530, COSV56058279; called by muse, mutect2, varscan2
- UGT2A1 | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 30/351 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs1270699532, COSV99684507; called by muse, mutect2
- ZNF391 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV55125266; called by muse, mutect2
- ZNF564 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 21/437 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV100212932; called by muse, mutect2
- ZNF746 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs374212094; called by muse, mutect2, varscan2
- ABCA7 | c.5311G>T p.E1771* | Nonsense Mutation (SNP) | VAF 24/442 reads (5%) | called by muse, mutect2
- ABCA7 | c.5312A>T p.E1771V | Missense Mutation (SNP) | VAF 27/446 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2
- ACBD5 | c.50T>A p.L17Q (on ENST00000375888 / NM_001352568.1; = p.L19Q on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- ADAM8 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 49/457 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- AGBL3 | c.1640G>A p.G547D | Missense Mutation (SNP) | VAF 25/325 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.108); called by muse, mutect2
- AMD1 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP2B3 | c.1756G>T p.V586F | Missense Mutation (SNP) | VAF 21/359 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2
- BEX4 | c.202A>G p.N68D | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); called by muse, mutect2
- BRWD3 | c.3650C>T p.A1217V | Missense Mutation (SNP) | VAF 17/337 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- C11orf54 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- C2CD4A | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 30/480 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); called by muse, mutect2
- CCAR1 | c.725C>G p.P242R | Missense Mutation (SNP) | VAF 29/361 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.202); called by muse, mutect2
- CD1D | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.923); called by muse, mutect2
- COL4A6 | c.1930C>A p.Q644K | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.627); called by muse, mutect2
- DCAF8 | c.1679_1680dup p.W561Afs*77 | Frame Shift Ins (INS) | VAF 36/407 reads (9%) | called by mutect2, pindel
- DIAPH1 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- DNAH5 | c.10445G>C p.C3482S | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- DNAI4 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- DNAJC6 | c.1798C>A p.L600M | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- E2F7 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- FAM71B | c.1208A>C p.Q403P | Missense Mutation (SNP) | VAF 34/452 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- FMN2 | c.4408A>C p.K1470Q | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FREM3 | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 37/372 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2
- GPC4 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 30/514 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- GPR39 | c.651G>C p.W217C | Missense Mutation (SNP) | VAF 46/560 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRM5 | c.192T>G p.Y64* | Nonsense Mutation (SNP) | VAF 37/342 reads (11%) | called by muse, mutect2, varscan2
- HAL | c.432G>C p.K144N | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- HIF1A | c.86G>C p.R29P | Missense Mutation (SNP) | VAF 54/324 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IFIT1 | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV1D-16 | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- KLK11 | c.294-1G>C p.X98_splice (on ENST00000594768 / NM_144947.3; = p.X66_splice on NM_006853.3) | Splice Site (SNP) | VAF 30/390 reads (8%) | called by muse, mutect2
- KMT2C | c.9645A>C p.K3215N | Missense Mutation (SNP) | VAF 61/410 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KRT25 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 27/356 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2
- LAMA2 | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, mutect2
- MPP4 | c.1904A>C p.E635A | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- NAB2 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 33/442 reads (7%) | called by muse, mutect2
- NLGN2 | c.1748T>A p.I583K | Missense Mutation (SNP) | VAF 44/401 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NTF4 | c.432T>A p.D144E | Missense Mutation (SNP) | VAF 39/500 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- NUP155 | c.3687G>C p.L1229F (on ENST00000231498 / NM_153485.3; = p.L1170F on NM_004298.4) | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.759); called by muse, mutect2
- OSBPL3 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 13/355 reads (4%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); called by muse, mutect2
- PARP10 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 32/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PITX1 | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.931); called by muse, mutect2
- PLXNB2 | c.14_29del p.L5Rfs*11 | Frame Shift Del (DEL) | VAF 52/350 reads (15%) | called by mutect2, pindel, varscan2
- POLH | c.1978C>G p.Q660E | Missense Mutation (SNP) | VAF 36/445 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2
- PPIL2 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 49/294 reads (17%) | called by muse, mutect2, varscan2
- PPP1R1C | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 17/454 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.554); called by muse, mutect2
- PRDM13 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 36/492 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- PRPF8 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PTCH1 | c.3309C>G p.A1103= | Splice Region (SNP) | VAF 20/239 reads (8%) | called by muse, mutect2
- QTRT1 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 28/362 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RAPH1 | c.3194C>A p.P1065H | Missense Mutation (SNP) | VAF 26/505 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ROBO3 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2
- SI | c.5178G>A p.W1726* | Nonsense Mutation (SNP) | VAF 37/261 reads (14%) | called by muse, mutect2, varscan2
- SLC38A10 | c.2259G>C p.E753D | Missense Mutation (SNP) | VAF 23/422 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2
- SNTB1 | c.1538A>T p.H513L | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SPAG9 | c.3172G>C p.D1058H (on ENST00000262013 / NM_001130528.3; = p.D1044H on NM_003971.6) | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- SRPX2 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 37/589 reads (6%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.967); called by muse, mutect2
- SYCE1 | c.871G>A p.A291T (on ENST00000343131 / NM_001143764.3; = p.A255T on NM_130784.3) | Missense Mutation (SNP) | VAF 35/412 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.184); called by muse, mutect2
- SYNE1 | c.18580G>T p.A6194S (on ENST00000367255 / NM_182961.4; = p.A6123S on NM_033071.3) | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- TBXAS1 | c.874A>C p.M292L | Missense Mutation (SNP) | VAF 16/458 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- TBXT | c.614C>G p.A205G | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.029); called by muse, mutect2
- TMEM190 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.192); called by muse, mutect2
- TOP2A | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.336); called by mutect2, varscan2
- TRAV23DV6 | c.225G>C p.L75F | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TRIM46 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 29/350 reads (8%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.593); called by muse, mutect2
- TRPA1 | c.1734G>C p.K578N | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2
- URB2 | c.1492C>T p.L498F | Missense Mutation (SNP) | VAF 38/672 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); called by muse, mutect2
- WWC2 | c.2187G>C p.L729F | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.028); called by muse, mutect2
- ZNF649 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- ZNF99 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.108); called by muse, mutect2
- ALDH1L1 | c.1857C>A p.P619= | Silent (SNP) | VAF 62/372 reads (17%) | called by muse, mutect2, varscan2
- AMER3 | c.1038G>T p.G346= | Silent (SNP) | VAF 48/538 reads (9%) | catalogued as COSV58465940; called by muse, mutect2
- ATXN1 | c.771C>G p.T257= | Silent (SNP) | VAF 46/478 reads (10%) | called by muse, mutect2
- CADPS2 | c.2409C>T p.V803= | Silent (SNP) | VAF 32/394 reads (8%) | called by muse, mutect2
- CBLN4 | c.138G>C p.S46= | Silent (SNP) | VAF 40/494 reads (8%) | catalogued as COSV50352358; called by muse, mutect2
- CCDC175 | c.1890A>G p.K630= | Silent (SNP) | VAF 27/176 reads (15%) | catalogued as rs1400704724, COSV55792096; called by muse, mutect2, varscan2
- CNGA2 | c.318G>A p.V106= | Silent (SNP) | VAF 32/560 reads (6%) | catalogued as COSV61706750; called by muse, mutect2
- COPS6 | c.111G>C p.G37= | Silent (SNP) | VAF 22/390 reads (6%) | called by muse, mutect2
- DIXDC1 | c.414G>T p.R138= | Silent (SNP) | VAF 43/445 reads (10%) | called by muse, mutect2
- FBXL7 | c.480G>A p.T160= | Silent (SNP) | VAF 30/458 reads (7%) | catalogued as rs764304989, COSV61640586; called by muse, mutect2
- GNRHR | c.390C>T p.F130= | Silent (SNP) | VAF 31/454 reads (7%) | catalogued as COSV56932884; called by muse, mutect2
- GSK3A | c.237C>T p.G79= | Silent (SNP) | VAF 40/446 reads (9%) | called by muse, mutect2
- IGSF1 | c.2739T>A p.V913= | Silent (SNP) | VAF 29/444 reads (7%) | called by muse, mutect2
- JUN | c.36T>C p.D12= | Silent (SNP) | VAF 20/344 reads (6%) | called by muse, mutect2
- KCTD3 | c.2292C>T p.F764= | Silent (SNP) | VAF 25/466 reads (5%) | catalogued as rs149998746; called by muse, mutect2
- LRP1B | c.582G>A p.K194= | Silent (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- MAST1 | c.4587C>T p.P1529= | Silent (SNP) | VAF 48/492 reads (10%) | catalogued as rs1375223384, COSV99263342; called by muse, mutect2
- NHLH1 | c.321C>T p.P107= | Silent (SNP) | VAF 40/563 reads (7%) | catalogued as rs534495739, COSV57483866; called by muse, mutect2
- NRDE2 | c.2478C>G p.L826= | Silent (SNP) | VAF 65/382 reads (17%) | catalogued as rs1052101167; called by muse, mutect2, varscan2
- NSD3 | c.3564C>A p.I1188= | Silent (SNP) | VAF 22/426 reads (5%) | catalogued as COSV57671621, COSV57674179; called by muse, mutect2
- PAN3 | c.1932A>G p.T644= | Silent (SNP) | VAF 16/199 reads (8%) | called by muse, mutect2
- PPP1R3A | c.2208A>G p.T736= | Silent (SNP) | VAF 27/424 reads (6%) | catalogued as rs909645644; called by muse, mutect2
- S1PR4 | c.903G>A p.A301= | Silent (SNP) | VAF 41/528 reads (8%) | catalogued as rs778351795; called by muse, mutect2
- SALL1 | c.1836C>A p.A612= | Silent (SNP) | VAF 23/359 reads (6%) | catalogued as COSV51753661; called by muse, mutect2
- SEC62 | c.99A>G p.P33= | Silent (SNP) | VAF 31/286 reads (11%) | called by muse, mutect2, varscan2
- SHBG | c.372G>T p.L124= | Silent (SNP) | VAF 24/343 reads (7%) | called by muse, mutect2
- SLC35E2B | c.339G>A p.L113= | Silent (SNP) | VAF 18/319 reads (6%) | catalogued as rs1452470106; called by muse, mutect2
- SOX13 | c.1644G>T p.R548= | Silent (SNP) | VAF 32/482 reads (7%) | called by muse, mutect2
- SPIN3 | c.114G>A p.R38= | Silent (SNP) | VAF 38/498 reads (8%) | called by muse, mutect2
- TPX2 | c.42G>A p.S14= | Silent (SNP) | VAF 34/309 reads (11%) | catalogued as rs758825961; called by muse, mutect2, varscan2
- TSC2 | c.3324G>A p.A1108= | Silent (SNP) | VAF 38/457 reads (8%) | catalogued as rs786203392; ClinVar: likely benign; called by muse, mutect2
- TSC2 | c.3663G>C p.S1221= | Silent (SNP) | VAF 26/330 reads (8%) | catalogued as rs137854268, CD078634, COSV54769110; called by muse, mutect2
- VGLL1 | c.267A>C p.P89= | Silent (SNP) | VAF 34/496 reads (7%) | called by muse, mutect2
- ZBTB21 | c.1050T>C p.V350= | Silent (SNP) | VAF 17/340 reads (5%) | called by muse, mutect2
- ZBTB46 | c.615C>T p.A205= | Silent (SNP) | VAF 47/527 reads (9%) | catalogued as rs139982660; called by muse, mutect2
- ZCCHC13 | c.300G>C p.L100= | Silent (SNP) | VAF 34/675 reads (5%) | called by muse, mutect2
- ZNF648 | c.669C>A p.V223= | Silent (SNP) | VAF 63/466 reads (14%) | called by mutect2, varscan2
- C20orf173 | c.-72A>T | 5'UTR (SNP) | VAF 28/368 reads (8%) | called by muse, mutect2
- C20orf173 | c.-73G>T | 5'UTR (SNP) | VAF 28/370 reads (8%) | called by muse, mutect2
- FGFR1 | c.-74G>T | 5'UTR (SNP) | VAF 20/564 reads (4%) | catalogued as COSV58343566; called by muse, mutect2
- ILF3 | chr19:10653411 T>G | 5'Flank (SNP) | VAF 32/268 reads (12%) | called by muse, mutect2, varscan2
- SCN1B | c.448+124G>A | Intron (SNP) | VAF 33/482 reads (7%) | catalogued as rs367608185; called by muse, mutect2
